Gene-level copy-number profile of tumor specimen TCGA-CN-6013-01A from TCGA case TCGA-CN-6013, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 56.7 years (20,703 days).
Specimen TCGA-CN-6013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e4a0cd96-81aa-41c8-b32c-1b6c57a08679.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6013-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5201335d-ad16-4997-86a9-31fbdb3b5f67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,847; copy number 2: 39,568; copy number 3: 13,603; copy number 4: 274; copy number 6: 2,357; copy number 7: 120; copy number 14: 6; copy number 16: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6013-01A-11D-1682-01): tumor purity 0.51, ploidy 2.34, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:31,657,890–32,077,580, 4 genes (within-gene range 0–1): OSBPL10, OSBPL10-AS1, ZNF587P1, ZNF860.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,522 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 6 (broad region; genes not listed).
- chr7:86,216,785–114,693,772, 537 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr11:69,147,228–72,573,229, 117 genes, copy number 7–16 (broad region; genes not listed).
- chr19:2,977,538–4,066,899, 55 genes, copy number 6: TLE6, TLE2, AC005944.1, TLE5, GNA11, AC005262.2, KF456478.1, AC005262.1, GNA15, AC005264.1, S1PR4, NCLN, CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1, MRPL54, RAX2, AC005777.1, MATK, ZFR2, FTLP5, ATCAY, RN7SL202P, NMRK2, DAPK3, MIR637, EEF2, SNORD37, PIAS4, ZBTB7A, AC016586.1.
- chr22:20,979,462–21,045,017, 13 genes, copy number 7 (within-gene range 2–7): AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P.

Autosomal genes at a single copy (total copy number 1): 3,847. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
